Gene-level copy-number profile of tumor specimen MP2PRT-PAVYXI-TMP1-A from MP2PRT case MP2PRT-PAVYXI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 6.0 years (2,207 days).
Specimen MP2PRT-PAVYXI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file bdd69678-d9b7-4cef-976f-472797d31c38.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAVYXI-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,727 have no estimate.
https://portal.gdc.cancer.gov/files/2c86433a-d066-4b7a-94d0-5fe1f5dce0cc

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 2; copy number 2: 629; copy number 3: 52; copy number 4: 42,728; copy number 5: 270; copy number 6: 11,211; copy number 7: 41; copy number 8: 3,906; copy number 9: 48.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:41,979,352–42,354,454, 7 genes: CR788268.1, RN7SL343P, SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2.
- chr14:22,438,547–22,439,015, 2 genes (within-gene range 0–6): TRDD1, TRDD2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 48 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:61,642,383–61,662,690, 2 genes, copy number 9: Y_RNA, AL935212.1.
- chr14:18,333,726–18,692,408, 19 genes, copy number 9: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11, CR383656.3, RPL22P20.
- chr21:13,305,152–13,848,364, 27 genes, copy number 9: AJ239318.1, FGF7P2, ANKRD30BP1, MIR3156-3, GTF2IP2, VN1R8P, LINC01674, SNX19P1, OR4K11P, OR4K12P, POTED, RNU6-286P, MIR3118-1, AL050303.2, GRAMD4P1, CXADRP1, AL050303.3, LONRF2P5, MIR8069-2, FEM1AP1, AL050303.1, TERF1P1, FAM207CP, GXYLT1P2, CNN2P7, ZNF114P1, CYP4F29P.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
